Somatic mutation profile of tumor specimen TCGA-2G-AAFV-01A (aliquot TCGA-2G-AAFV-01A-11D-A42Y-10) from TCGA case TCGA-2G-AAFV, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Yolk sac tumor; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IS; Age at diagnosis: 31.8 years (11,598 days).
Specimen TCGA-2G-AAFV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f94cef5a-c5b2-42f2-9bbd-61c91e3c4e9d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2G-AAFV-10A (Blood Derived Normal), aliquot TCGA-2G-AAFV-10A-01D-A433-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4a04c235-0f52-42cf-9dae-18bf3443cdc3

The open-access MAF lists 22 somatic variants for this specimen: 19 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 15, Silent 3, Frame Shift Del 2, Nonsense Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MAG | c.1346G>A p.R449H | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.861); catalogued as rs764422265; called by muse, mutect2, varscan2
- PDYN | c.254A>C p.K85T | Missense Mutation (SNP) | VAF 47/138 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.05); catalogued as COSV54101604; called by muse, mutect2, varscan2
- RALGAPA1 | c.1764_1765del p.R588Sfs*56 | Frame Shift Del (DEL) | VAF 30/224 reads (13%) | catalogued as rs1307468234; called by pindel, varscan2
- ACADM | c.1243C>G p.H415D | Missense Mutation (SNP) | VAF 58/378 reads (15%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.969); called by muse, varscan2
- ARFGEF1 | c.466C>T p.L156F | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ATP8A2 | c.1336G>T p.A446S | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.442); called by muse, mutect2
- C12orf40 | c.776A>G p.Y259C | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.54); called by muse, mutect2, varscan2
- CAND2 | c.1027G>A p.D343N (on ENST00000456430 / NM_001162499.2; = p.D250N on NM_012298.3) | Missense Mutation (SNP) | VAF 21/108 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ELAPOR2 | c.385T>G p.S129A | Missense Mutation (SNP) | VAF 38/144 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- JADE1 | c.1550G>T p.R517L | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- KCTD8 | c.658G>C p.V220L | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- LRRK2 | c.7147C>T p.L2383F | Missense Mutation (SNP) | VAF 30/125 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.701); called by muse, mutect2, varscan2
- PKD1L3 | c.1995T>G p.C665W | Missense Mutation (SNP) | VAF 53/147 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC1A2 | c.11C>T p.T4M | Missense Mutation (SNP) | VAF 42/151 reads (28%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- TDRD15 | c.4564G>T p.E1522* | Nonsense Mutation (SNP) | VAF 14/400 reads (4%) | called by muse, mutect2
- TOP1 | c.2239_2255del p.T747Cfs*5 | Frame Shift Del (DEL) | VAF 24/94 reads (26%) | called by mutect2, pindel, varscan2
- TRIP12 | c.2426-1G>C p.X809_splice | Splice Site (SNP) | VAF 35/247 reads (14%) | called by muse, mutect2, varscan2
- ULBP2 | c.406A>T p.S136C | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- ZZEF1 | c.959C>T p.A320V | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.801); called by muse, mutect2
- ADORA1 | c.198C>T p.A66= | Silent (SNP) | VAF 13/190 reads (7%) | called by muse, mutect2
- ARMC8 | c.427C>T p.L143= (on ENST00000469044 / NM_001363941.2; = p.L129= on NM_014154.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 16/92 reads (17%) | catalogued as rs763429972; called by mutect2, varscan2
- TRAF7 | c.381G>T p.V127= | Silent (SNP) | VAF 3/47 reads (6%) | catalogued as rs1235291985; called by muse, mutect2
